Somatic mutation profile of tumor specimen TCGA-DD-AACK-01A (aliquot TCGA-DD-AACK-01A-11D-A40R-10) from TCGA case TCGA-DD-AACK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.6 years (25,796 days).
Specimen TCGA-DD-AACK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b383db58-59c3-440b-9432-71ab53024e09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACK-10A (Blood Derived Normal), aliquot TCGA-DD-AACK-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbe86331-ca8f-44a3-928e-00dfdca42ad0

The open-access MAF lists 156 somatic variants for this specimen: 120 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 33, Nonsense Mutation 15, Frame Shift Del 5, Splice Region 2, Intron 2, In Frame Del 2, Frame Shift Ins 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 39/117 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58682804, COSV58699096, COSV58719034; called by muse, mutect2, varscan2
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, varscan2
- DYRK1A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as rs724159953, CM1510739, COSV58292386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2328A>C p.L776F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99177045; called by muse, mutect2, varscan2
- AFTPH | c.2106G>T p.W702C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99480485; called by muse, mutect2, varscan2
- AKR1D1 | c.48C>A p.N16K | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99652952; called by muse, mutect2, varscan2
- ALB | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as CM050168, COSV99890637; called by muse, mutect2, varscan2
- AP3D1 | c.272A>T p.K91M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642546; called by mutect2, varscan2
- AREL1 | c.1219A>T p.I407F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100707587; called by muse, mutect2, varscan2
- ARFGEF2 | c.2180G>C p.R727P | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904180; called by muse, mutect2, varscan2
- ARHGEF7 | c.1264A>T p.R422* (on ENST00000375741 / NM_001113511.2; = p.R244* on NM_003899.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99521326; called by muse, mutect2, varscan2
- CACNA1E | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV62389899; called by muse, mutect2
- CAND1 | c.2044A>T p.S682C | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV101607309; called by muse, mutect2, varscan2
- CARD14 | c.2201C>G p.T734S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100712531; called by muse, mutect2, varscan2
- CCDC93 | c.649A>T p.M217L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100098602; called by muse, mutect2, varscan2
- CCT6A | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99303362; called by muse, mutect2, varscan2
- CDH4 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100848651; called by muse, mutect2, varscan2
- CNGA4 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as COSV101171781; called by muse, mutect2, varscan2
- COL2A1 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV100476055; called by muse, mutect2, varscan2
- CREB3 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100147550; called by muse, mutect2, varscan2
- CRY2 | c.758A>T p.Y253F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101314570; called by muse, mutect2, varscan2
- CSTF2T | c.1721A>T p.Q574L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100484136; called by muse, mutect2, varscan2
- DEFB106B | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100128905; called by muse, mutect2, varscan2
- DHRS9 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100513407; called by muse, mutect2
- DMKN | c.1177A>T p.S393C | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100303422; called by muse, mutect2, varscan2
- DNAH2 | c.662T>A p.L221H | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99318061; called by muse, mutect2, varscan2
- DNAH7 | c.5719T>A p.F1907I | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100414588; called by muse, mutect2, varscan2
- DNER | c.1414T>A p.C472S | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100518761; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56128202, COSV99818049; called by muse, mutect2
- EEF1A1 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303255; called by muse, mutect2, varscan2
- ENTPD2 | c.1250A>T p.E417V (on ENST00000355097 / NM_203468.3; = p.E394V on NM_001246.4) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100445702; called by muse, mutect2, varscan2
- EVC2 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100185577, COSV60400640; called by muse, mutect2, varscan2
- EVPL | c.3041T>A p.L1014Q | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100044292; called by muse, mutect2, varscan2
- FAAP100 | c.1516A>G p.I506V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV100585302; called by muse, mutect2, varscan2
- FAM135A | c.338T>A p.L113* (on ENST00000370479 / NM_001351599.1; = p.L70* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV99525564; called by muse, mutect2, varscan2
- FBXL4 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs1331125714, COSV100014005; called by muse, mutect2, varscan2
- FLI1 | c.874T>A p.S292T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV99857567; called by muse, mutect2, varscan2
- FRAS1 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs371136161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP2 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1241007974, COSV100975367; called by muse, mutect2, varscan2
- GIGYF2 | c.2979C>G p.S993R | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV101004212; called by muse, mutect2, varscan2
- GPR68 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473421; called by muse, mutect2, varscan2
- GYPB | c.142A>T p.T48S | Missense Mutation (SNP) | VAF 168/409 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99301465; called by muse, mutect2, varscan2
- HIVEP2 | c.7235A>T p.K2412M | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99171933; called by muse, mutect2, varscan2
- HSPG2 | c.3395A>T p.Y1132F | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101020579; called by muse, mutect2, varscan2
- HUWE1 | c.12809A>T p.K4270M | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99471472; called by muse, mutect2, varscan2
- IGSF3 | c.3472T>A p.S1158T (on ENST00000369486 / NM_001007237.3; = p.S1178T on NM_001542.4) | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100604432; called by muse, mutect2, varscan2
- IL10RB | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV99269862; called by muse, mutect2, varscan2
- IL4I1 | c.796T>A p.W266R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV99680542; called by muse, mutect2, varscan2
- INTS4 | c.1718A>T p.Y573F | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV101417159; called by muse, mutect2, varscan2
- IRAK3 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV99706065; called by muse, mutect2, varscan2
- ISG20L2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493962; called by muse, mutect2, varscan2
- ITGB2 | c.1307A>T p.Q436L (on ENST00000302347; = p.Q412L on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100185743; called by muse, mutect2, varscan2
- KCNS2 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99750987; called by muse, mutect2, varscan2
- KIF2B | c.725A>T p.N242I | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99275065; called by muse, mutect2
- KRT10 | c.1253T>A p.L418* | Nonsense Mutation (SNP) | VAF 56/130 reads (43%) | catalogued as COSV99509999; called by muse, mutect2, varscan2
- LRBA | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100841281; called by muse, mutect2, varscan2
- MARCO | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100503356; called by muse, mutect2, varscan2
- MBOAT2 | c.949T>A p.W317R | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100019989; called by muse, mutect2, varscan2
- MC4R | c.791A>T p.H264L | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235936; called by muse, mutect2, varscan2
- MCM6 | c.968A>T p.E323V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99918903; called by muse, mutect2, varscan2
- MOCOS | c.335A>T p.Y112F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99733082; called by muse, mutect2, varscan2
- MRPL47 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99372909; called by muse, mutect2, varscan2
- MTNR1A | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV100208165; called by muse, mutect2
- MYH7 | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100805912; called by muse, mutect2, varscan2
- MYT1 | c.1042T>A p.S348T | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV100114360; called by muse, mutect2, varscan2
- NCAPD2 | c.4013T>C p.V1338A | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99975456; called by muse, mutect2, varscan2
- NEB | c.4094A>T p.Q1365L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as rs375155384; called by muse, mutect2, varscan2
- NR3C2 | c.484A>T p.R162* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs1553943244, COSV100678865; called by muse, mutect2, varscan2
- ODC1 | c.985A>G p.I329V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV99301242; called by muse, varscan2
- ODF2L | c.1456C>A p.L486M (on ENST00000317336; = p.L457M on NM_020729.3) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99643992; called by muse, mutect2, varscan2
- OLIG2 | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100324216; called by muse, mutect2, varscan2
- OR4A15 | c.4A>T p.K2* | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100123958; called by muse, mutect2, varscan2
- ORC2 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99309484, COSV99309668; called by muse, mutect2, varscan2
- PDGFC | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99925085; called by muse, mutect2, varscan2
- PDHA2 | c.317T>A p.I106K | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV54779893; called by muse, varscan2
- PDIA2 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99249585; called by muse, mutect2
- PELI2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50710031; called by muse, mutect2, varscan2
- PHIP | c.3025A>G p.I1009V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV51510658; called by muse, mutect2, varscan2
- PNPLA1 | c.802A>T p.K268* (on ENST00000394571 / NM_001374623.1; = p.K173* on NM_173676.2) | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100462923; called by muse, mutect2, varscan2
- POTEF | c.810G>A p.K270= | Splice Region (SNP) | VAF 51/229 reads (22%) | catalogued as rs1007386025, COSV100664732; called by muse, varscan2
- PRICKLE1 | c.752G>C p.C251S | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100566210; called by muse, mutect2, varscan2
- PRKCG | c.1809T>A p.D603E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99668803; called by muse, mutect2, varscan2
- PRR5 | c.820G>T p.G274C (on ENST00000336985 / NM_181333.4; = p.G265C on NM_015366.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99134194; called by muse, mutect2, varscan2
- PRUNE2 | c.1739A>T p.N580I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.113); catalogued as COSV100944397; called by muse, mutect2, varscan2
- PXDNL | c.1980A>C p.R660S | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100682860; called by muse, mutect2, varscan2
- RAB33A | c.331C>A p.H111N | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.531); catalogued as COSV99924517; called by muse, mutect2, varscan2
- RAD23B | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100787668; called by muse, mutect2, varscan2
- RASD2 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as COSV99332725; called by mutect2, varscan2
- RAVER2 | c.2040C>A p.Y680* (on ENST00000294428 / NM_001366165.1; = p.Y667* on NM_018211.4) | Nonsense Mutation (SNP) | VAF 68/201 reads (34%) | catalogued as COSV99605013; called by muse, mutect2, varscan2
- SEMA3E | c.1078A>T p.K360* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as COSV100318058; called by muse, varscan2
- SH3TC2 | c.3044A>G p.N1015S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as rs1209299386, COSV100101482; called by muse, mutect2, varscan2
- SLC22A8 | c.985T>A p.C329S | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100267811; called by muse, mutect2, varscan2
- SLC39A12 | c.928T>A p.C310S | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101069981; called by muse, mutect2, varscan2
- SLC44A5 | c.2063G>C p.R688T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100901687, COSV63758614, COSV63765097; called by muse, mutect2, varscan2
- SMARCD1 | c.1540A>G p.N514D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as COSV99993756; called by muse, mutect2, varscan2
- SNX8 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1300724825, COSV99770718; called by muse, mutect2, varscan2
- SPEN | c.3166A>T p.R1056* | Nonsense Mutation (SNP) | VAF 66/177 reads (37%) | catalogued as COSV65363154; called by muse, mutect2, varscan2
- SYT7 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99801372; called by muse, mutect2, varscan2
- TAF15 | c.1360G>A p.G454S (on ENST00000605844 / NM_139215.3; = p.G451S on NM_003487.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1410045851; called by muse, mutect2, varscan2
- TCTN2 | c.2089A>T p.S697C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV100315158; called by muse, mutect2, varscan2
- TNRC18 | c.5501A>T p.E1834V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101269616; called by muse, mutect2, varscan2
- TPRX1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs765636340, COSV100445608; called by muse, mutect2, varscan2
- TRIO | c.3038C>G p.S1013C | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100710174, COSV100710952; called by muse, mutect2, varscan2
- TTN | c.48048A>T p.E16016D (on ENST00000591111; = p.E8592D on NM_003319.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | PolyPhen benign (0.21); catalogued as COSV100603624; called by muse, mutect2, varscan2
- UACA | c.3473A>C p.N1158T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as COSV100537421; called by muse, mutect2, varscan2
- USP29 | c.267C>A p.Y89* | Nonsense Mutation (SNP) | VAF 60/172 reads (35%) | catalogued as COSV99572001; called by muse, mutect2, varscan2
- VLDLR | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs767529669, COSV66073663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDFY3 | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99882922; called by muse, mutect2, varscan2
- ZMYM4 | c.1719A>T p.A573= | Splice Region (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100109990; called by muse, mutect2, varscan2
- ZNF416 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs765573804, COSV99543736; called by muse, mutect2, varscan2
- ZNF681 | c.664G>T p.G222* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV101267430; called by muse, mutect2, varscan2
- CDK18 | c.946_989del p.L316Gfs*23 (on ENST00000506784 / NM_212503.3; = p.L286Gfs*23 on NM_002596.4) | Frame Shift Del (DEL) | VAF 53/200 reads (27%) | called by mutect2, pindel
- CUX1 | c.4376_4387del p.L1459_L1462del | In Frame Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- GJB1 | c.89_94dup p.I30_F31dup | In Frame Ins (INS) | VAF 32/46 reads (70%) | called by mutect2, varscan2
- HCN1 | c.1534dup p.M512Nfs*17 | Frame Shift Ins (INS) | VAF 37/116 reads (32%) | called by mutect2, varscan2
- HDAC4 | c.3090_3091del p.L1031Afs*44 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | called by mutect2, pindel*, varscan2*
- MYH15 | c.4818del p.I1606Mfs*21 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, varscan2
- NGRN | c.32_41del p.G11Afs*44 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- SUCLA2 | c.1421_1426del p.A474_H475del (on ENST00000643023; = p.A453_H454del on NM_003850.3) | In Frame Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- THAP11 | c.481_491del p.Q161Rfs*75 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- B9D2 | c.384G>T p.V128= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV99699107; called by muse, mutect2, varscan2
- BAG4 | c.492T>C p.S164= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV99781775; called by muse, mutect2, varscan2
- BASP1 | c.252G>A p.K84= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs1363945940, COSV100493666; called by muse, mutect2, varscan2
- CACNA1I | c.4788G>T p.L1596= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100359816; called by muse, mutect2, varscan2
- CCNL2 | c.327C>T p.F109= | Silent (SNP) | VAF 74/134 reads (55%) | catalogued as rs1215265521, COSV61224191; called by muse, varscan2
- CD200R1 | c.12T>A p.P4= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99867033; called by muse, mutect2, varscan2
- CLEC1A | c.759G>A p.K253= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100191310; called by muse, mutect2
- COL17A1 | c.3648T>A p.P1216= | Silent (SNP) | VAF 121/324 reads (37%) | catalogued as COSV100793112; called by muse, varscan2
- CYP4B1 | c.393G>T p.G131= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs755650253, COSV99596705, COSV99596968; called by muse, mutect2, varscan2
- FER1L6 | c.1704T>C p.N568= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV101205700; called by muse, mutect2, varscan2
- FOXD3 | c.1095G>A p.A365= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100942838; called by muse, mutect2, varscan2
- GALNT17 | c.1245A>T p.I415= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100353271; called by muse, mutect2, varscan2
- GATA3 | c.207G>A p.R69= | Silent (SNP) | VAF 85/212 reads (40%) | catalogued as COSV100650916; called by muse, mutect2, varscan2
- GPHN | c.1630T>C p.L544= (on ENST00000315266 / NM_001377519.1; = p.L577= on NM_020806.5) | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV100015856; called by muse, mutect2, varscan2
- ICAM1 | c.1281C>T p.P427= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs556280231, COSV99320671; called by muse, mutect2, varscan2
- INSM2 | c.465A>T p.A155= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99354119; called by muse, mutect2, varscan2
- LAMA2 | c.7959G>A p.Q2653= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV70345263; called by muse, mutect2, varscan2
- MAPK11 | c.163C>T p.L55= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV100404430; called by muse, mutect2, varscan2
- MED16 | c.2574A>T p.T858= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99515414; called by muse, mutect2, varscan2
- MPP7 | c.75G>T p.L25= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as COSV100517207, COSV61739861; called by muse, mutect2, varscan2
- NRXN3 | c.2421T>G p.R807= (on ENST00000335750 / NM_001330195.2; = p.R434= on NM_004796.6) | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100202564; called by muse, mutect2, varscan2
- PCDH11Y | c.48T>A p.S16= | Silent (SNP) | VAF 110/161 reads (68%) | catalogued as COSV99291074; called by muse, mutect2, varscan2
- PDHA2 | c.318A>T p.I106= | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as COSV99756728; called by muse, varscan2
- PLAC8 | c.207A>G p.A69= | Silent (SNP) | VAF 80/206 reads (39%) | catalogued as COSV100274467; called by muse, mutect2, varscan2
- PRAMEF17 | c.378A>G p.P126= | Silent (SNP) | VAF 93/282 reads (33%) | catalogued as COSV101068699; called by muse, mutect2
- PRUNE2 | c.5238A>T p.P1746= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100944396; called by muse, varscan2
- STK36 | c.3741A>T p.P1247= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV99831186; called by muse, mutect2, varscan2
- SYNM | c.1041A>G p.S347= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100152615; called by muse, mutect2, varscan2
- UBR4 | c.8742G>T p.R2914= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100920651; called by muse, mutect2, varscan2
- WHRN | c.1995G>T p.L665= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99470076; called by muse, mutect2, varscan2
- ZMYM6 | c.3882A>T p.S1294= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100593103; called by muse, mutect2, varscan2
- ZNF646 | c.2901C>T p.Y967= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs140492151; called by muse, mutect2, varscan2
- ZNF831 | c.2637T>A p.P879= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as COSV100925943; called by muse, mutect2, varscan2
- LYSMD4 | c.282+333A>T | Intron (SNP) | VAF 141/361 reads (39%) | catalogued as COSV100230582; called by muse, varscan2
- RBM44 | c.-98-1786A>G | Intron (SNP) | VAF 90/205 reads (44%) | catalogued as COSV100389725; called by muse, mutect2, varscan2
- SSPOP | n.7202T>A | RNA (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100022328; called by muse, mutect2, varscan2
